Somatic mutation profile of tumor specimen TCGA-29-1693-01A (aliquot TCGA-29-1693-01A-01W-0633-09) from TCGA case TCGA-29-1693, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.0 years (26,300 days).
Specimen TCGA-29-1693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13e782af-cd7f-4606-8b2a-0b02904081dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1693-10A (Blood Derived Normal), aliquot TCGA-29-1693-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa4a7d37-9064-43bc-bb3f-dc5b0fa30885

The open-access MAF lists 117 somatic variants for this specimen: 89 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 26, Frame Shift Del 5, In Frame Del 4, Splice Site 3, Frame Shift Ins 2, Nonsense Mutation 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.9513_9516del p.L3172Afs*44 | Frame Shift Del (DEL) | VAF 103/135 reads (76%) | catalogued as rs80359769; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PMS2 | c.325dup p.E109Gfs*30 | Frame Shift Ins (INS) | VAF 6/44 reads (14%) | catalogued as rs587781716; ClinVar: pathogenic; called by mutect2, varscan2
- ADAMTS1 | c.1583G>C p.W528S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53170931, COSV53171284; called by muse, mutect2, varscan2
- ADAMTS12 | c.1480-2A>G p.X494_splice | Splice Site (SNP) | VAF 168/303 reads (55%) | catalogued as COSV61266684; called by muse, mutect2, varscan2
- AGER | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100905016; called by muse, mutect2
- ALS2 | c.4144C>A p.P1382T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99969940; called by muse, mutect2
- ARID2 | c.4477G>A p.V1493I | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV57599059, COSV99044006; called by muse, mutect2
- ATM | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 64/117 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs201719927, COSV53752249; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BICDL1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99985938; called by muse, mutect2
- C1D | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878255; called by muse, mutect2, varscan2
- CCT8L2 | c.614T>A p.V205E | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63462898; called by muse, mutect2, varscan2
- CDV3 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV99394413; called by muse, mutect2
- CNIH4 | c.331A>T p.M111L | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs779278796, COSV64796198; called by muse, mutect2, varscan2
- CNN3 | c.926A>G p.H309R | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs1408772372, COSV54731308; called by muse, mutect2, varscan2
- DEFB127 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV66688871; called by muse, mutect2, varscan2
- DMTF1 | c.1807C>A p.P603T | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.415); catalogued as COSV57538702; called by muse, mutect2, varscan2
- DMXL1 | c.6844G>C p.D2282H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV60714655; called by muse, mutect2, varscan2
- DNAH10 | c.1516G>C p.E506Q (on ENST00000409039; = p.E445Q on NM_207437.3) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV68995933; called by muse, mutect2, varscan2
- DSN1 | c.427del p.Q143Sfs*11 | Frame Shift Del (DEL) | VAF 118/239 reads (49%) | catalogued as COSV65519909; called by mutect2, pindel, varscan2
- EDNRA | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs188759418, COSV60100559; called by muse, mutect2, varscan2
- EGR2 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.176); catalogued as COSV54347405; called by muse, mutect2, varscan2
- EIF2A | c.1168T>C p.W390R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56407393; called by muse, mutect2, varscan2
- EIF4G1 | c.3938C>A p.A1313D (on ENST00000346169 / NM_198241.3; = p.A1118D on NM_004953.5) | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV100072240; called by muse, mutect2
- ERBB4 | c.1985T>C p.F662S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99631257; called by muse, mutect2
- ETFDH | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56988249; called by muse, mutect2, varscan2
- FAM111A | c.263del p.R88Kfs*5 | Frame Shift Del (DEL) | VAF 43/131 reads (33%) | catalogued as COSV64655468; called by mutect2, pindel, varscan2
- GAL3ST1 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58892935; called by muse, mutect2, varscan2
- GUCA1B | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57835497; called by muse, mutect2, varscan2
- HSPA6 | c.473A>G p.Q158R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); catalogued as COSV59061521; called by muse, mutect2, varscan2
- HSPB8 | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV56138413; called by muse, mutect2, varscan2
- IGSF9 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV63640654; called by muse, mutect2, varscan2
- KLHL40 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 11/14 reads (79%) | catalogued as COSV55135251; called by muse, mutect2, varscan2
- LRRC3B | c.639G>C p.W213C | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67521596; called by muse, mutect2, varscan2
- LRRC6 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as rs1379337413, COSV51543635; called by muse, mutect2, varscan2
- MAP1B | c.3912A>T p.E1304D | Missense Mutation (SNP) | VAF 137/371 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV57101163, COSV57107446; called by muse, mutect2, varscan2
- MC3R | c.386T>A p.V129E | Missense Mutation (SNP) | VAF 87/380 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54764119; called by muse, mutect2, varscan2
- MECOM | c.2411A>G p.N804S (on ENST00000468789 / NM_001105078.4; = p.N992S on NM_004991.4) | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV52967259; called by muse, mutect2, varscan2
- MEP1A | c.95T>G p.V32G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100043053; called by muse, mutect2, varscan2
- MIDEAS | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV54095787; called by muse, mutect2, varscan2
- MOK | c.496T>A p.W166R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51965217, COSV51965737; called by muse, mutect2, varscan2
- MYO5B | c.3617A>C p.E1206A | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV53222174; called by muse, mutect2, varscan2
- NAP1L3 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100220587, COSV100220615; called by muse, mutect2
- NOMO3 | c.785A>T p.D262V | Missense Mutation (SNP) | VAF 87/241 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as rs1272133011, COSV53770031, COSV99530657; called by muse, mutect2, varscan2
- NUP62 | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV61312552; called by muse, mutect2, varscan2
- OPTN | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53811480; called by muse, mutect2, varscan2
- OR10R2 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 26/614 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100936834; called by muse, mutect2
- OR1F1 | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV100484497; called by muse, mutect2
- OR6N2 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 51/846 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100210288, COSV100210443; called by muse, mutect2
- OVOL2 | c.329C>G p.T110R | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as COSV53860925; called by muse, mutect2, varscan2
- PAK3 | c.19A>G p.N7D | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV53276344; called by muse, mutect2, varscan2
- PIK3C3 | c.2360T>C p.M787T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV56281003; called by muse, mutect2, varscan2
- PLA1A | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV99845782; called by muse, mutect2
- PLEC | c.541C>A p.Q181K (on ENST00000322810 / NM_201380.4; = p.Q71K on NM_000445.5) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV100518245; called by muse, mutect2
- PPEF2 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs771997780, COSV54423567; called by muse, varscan2
- PTK2B | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV57759339; called by muse, mutect2, varscan2
- RINT1 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV57559122; called by muse, mutect2, varscan2
- SERPINA3 | c.586A>C p.I196L | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV101261798; called by muse, mutect2
- SLC44A4 | c.1219T>G p.S407A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV57667850; called by muse, mutect2, varscan2
- SMARCC1 | c.2242T>C p.S748P | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); catalogued as COSV54382668; called by muse, mutect2, varscan2
- SMARCD3 | c.981G>T p.Q327H (on ENST00000262188 / NM_001003801.2; = p.Q314H on NM_003078.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs1231086453, COSV50392674; called by muse, mutect2, varscan2
- SPOPL | c.852_860del p.L285_V287del | In Frame Del (DEL) | VAF 61/91 reads (67%) | catalogued as COSV54514254; called by mutect2, pindel, varscan2
- SYNJ2 | c.2563C>T p.H855Y | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100840622; called by muse, mutect2
- TAMALIN | c.324T>A p.D108E | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV53337053; called by muse, mutect2, varscan2
- TBC1D2B | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316900, COSV56043345; called by muse, mutect2, varscan2
- TMEFF2 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as COSV55834637; called by muse, mutect2, varscan2
- TMEM144 | c.766A>G p.N256D | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as COSV99646960; called by muse, mutect2
- TMEM214 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs752364794, COSV99476503; called by muse, mutect2, varscan2
- TMEM214 | c.489C>G p.S163R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV99476505; called by muse, mutect2, varscan2
- TP53 | c.304del p.T102Pfs*21 | Frame Shift Del (DEL) | VAF 133/253 reads (53%) | catalogued as COSV53305997; called by mutect2, pindel, varscan2
- TRPM3 | c.2644-2A>T p.X882_splice (on ENST00000357533 / NM_001366142.2; = p.X725_splice on NM_020952.6) | Splice Site (SNP) | VAF 25/85 reads (29%) | catalogued as COSV100678532; called by muse, mutect2, varscan2
- TSEN54 | c.611G>C p.S204T | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV51360167; called by muse, mutect2, varscan2
- TSGA10IP | c.661G>C p.G221R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV73245328; called by muse, mutect2, varscan2
- UBA52 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV55889757; called by muse, mutect2, varscan2
- UROC1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV52030084; called by muse, mutect2, varscan2
- UTRN | c.3242C>A p.T1081N | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.11); catalogued as COSV62339113; called by muse, mutect2, varscan2
- WDFY2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV53290683; called by muse, mutect2, varscan2
- XKR3 | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58886765; called by muse, mutect2, varscan2
- YEATS2 | c.1514A>C p.Q505P | Missense Mutation (SNP) | VAF 221/320 reads (69%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.153); catalogued as COSV59367602; called by muse, mutect2, varscan2
- ZNF319 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99540429; called by muse, mutect2
- ZNF528 | c.368T>G p.F123C | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV64619903; called by muse, mutect2, varscan2
- ZNF638 | c.1268T>A p.I423K | Missense Mutation (SNP) | VAF 96/131 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV52490199; called by muse, mutect2, varscan2
- ZNF644 | c.2012C>G p.S671* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV100494260, COSV61348472; called by muse, mutect2, varscan2
- ZNF653 | c.343+2T>C p.X115_splice | Splice Site (SNP) | VAF 126/523 reads (24%) | catalogued as COSV53403583; called by muse, mutect2, varscan2
- AP3M1 | c.1029_1056delinsT p.G344_P352del | In Frame Del (DEL) | VAF 35/63 reads (56%) | called by pindel, varscan2*
- COL9A2 | c.908dup p.G304Rfs*50 | Frame Shift Ins (INS) | VAF 4/37 reads (11%) | called by pindel, varscan2
- HEATR1 | c.5356_5370del p.V1786_E1790del | In Frame Del (DEL) | VAF 36/187 reads (19%) | called by mutect2, pindel, varscan2
- IGF1R | c.1647G>C p.W549C | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRTAP9-9 | c.507_509del p.C169del | In Frame Del (DEL) | VAF 247/346 reads (71%) | called by pindel, varscan2
- RBPJ | c.249_264del p.K83Nfs*18 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by pindel, varscan2
- ABCC5 | c.2832C>T p.S944= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV55592257; called by muse, mutect2, varscan2
- CNR1 | c.1044C>T p.I348= | Silent (SNP) | VAF 85/180 reads (47%) | catalogued as COSV62988599; called by muse, mutect2, varscan2
- CRACD | c.2028G>C p.L676= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV51724420; called by muse, mutect2, varscan2
- DNAJC1 | c.1581C>T p.V527= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as COSV100981420; called by muse, mutect2
- EPHA10 | c.2430G>A p.A810= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as rs780958682, COSV57624881; called by muse, mutect2, varscan2
- FLNC | c.978G>C p.V326= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57958173; called by muse, mutect2, varscan2
- GRIA2 | c.1848C>T p.S616= | Silent (SNP) | VAF 9/172 reads (5%) | catalogued as rs1355407054, COSV52393683; called by muse, mutect2
- HIVEP1 | c.4050C>T p.G1350= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as COSV65102798; called by muse, mutect2, varscan2
- IL12RB2 | c.1245C>T p.N415= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV99255587; called by muse, mutect2
- LCOR | c.1140T>C p.D380= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV53716800; called by muse, mutect2, varscan2
- NOL11 | c.1572G>A p.E524= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as COSV53524070; called by muse, mutect2, varscan2
- OR7A17 | c.498G>C p.L166= | Silent (SNP) | VAF 151/377 reads (40%) | catalogued as rs764771647, COSV59414550; called by muse, mutect2, varscan2
- PKD2L1 | c.921C>A p.V307= | Silent (SNP) | VAF 220/282 reads (78%) | catalogued as COSV58396720; called by muse, mutect2, varscan2
- PLD1 | c.1017A>T p.R339= | Silent (SNP) | VAF 258/346 reads (75%) | catalogued as COSV60569650; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2199C>T p.A733= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs772010189, COSV53453665; called by muse, mutect2, varscan2
- PTPRD | c.3192T>C p.D1064= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV61957312; called by muse, mutect2, varscan2
- PTPRO | c.828G>A p.S276= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs745339233, COSV55513642; called by muse, mutect2, varscan2
- RETREG1 | c.366C>T p.V122= | Silent (SNP) | VAF 65/204 reads (32%) | catalogued as rs374947524; called by muse, mutect2, varscan2
- RHBDF2 | c.2052G>A p.L684= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs1377694006, COSV51685262; called by muse, mutect2, varscan2
- RSPH1 | c.261A>C p.G87= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV52319981; called by muse, mutect2, varscan2
- SLC12A1 | c.1482C>T p.P494= | Silent (SNP) | VAF 241/920 reads (26%) | catalogued as rs747363549, COSV66796368; called by muse, mutect2, varscan2
- SPTA1 | c.4203G>A p.Q1401= | Silent (SNP) | VAF 31/229 reads (14%) | catalogued as COSV63755436; called by muse, mutect2, varscan2
- STXBP3 | c.330C>T p.F110= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV64182575; called by muse, mutect2
- TOX3 | c.123G>A p.E41= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as COSV99568045; called by muse, mutect2
- ZBTB46 | c.105G>T p.V35= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55511389; called by muse, mutect2, varscan2
- ZNF630 | c.1365A>G p.G455= | Silent (SNP) | VAF 67/97 reads (69%) | catalogued as COSV52096801; called by muse, mutect2, varscan2
- DST | c.4297-2737C>A | Intron (SNP) | VAF 137/252 reads (54%) | catalogued as COSV55022574; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3245C>T | Intron (SNP) | VAF 40/150 reads (27%) | catalogued as COSV60360348; called by muse, varscan2
